Somatic mutation profile of tumor specimen TCGA-HC-8258-01A (aliquot TCGA-HC-8258-01A-11D-2260-08) from TCGA case TCGA-HC-8258, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.7 years (20,703 days).
Specimen TCGA-HC-8258-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13db4268-7f47-4144-af46-587e63119271.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8258-10A (Blood Derived Normal), aliquot TCGA-HC-8258-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a83a75c-cbba-4082-8fec-624cc91e882f

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA2C | c.1301C>G p.P434R | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57467420; called by muse, mutect2
- ENTPD7 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs1013401025, COSV65112431; called by muse, mutect2, varscan2
- FLG | c.1510T>C p.S504P | Missense Mutation (SNP) | VAF 35/811 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs766808539, COSV64242929; called by muse, mutect2
- NOMO3 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs370050651; called by muse, mutect2, varscan2
- OR4C6 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.354); catalogued as COSV58604485; called by muse, mutect2
- TRPV2 | c.1787C>A p.A596D | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV58428778; called by muse, mutect2
- USF3 | c.1848T>A p.N616K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.272); catalogued as COSV57074033; called by muse, mutect2, varscan2
- ZFP69 | c.731A>C p.K244T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV65529120; called by mutect2, varscan2
